TCGA case TCGA-90-6837 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0e515ab8-99f9-43d9-a621-8fe9ede828ec

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.8; Tissue or organ of origin: Overlapping lesion of lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.4 years (23,511 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 758 days (2.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 148 days; Days to treatment end: 176 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 148 days; Days to treatment end: 176 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 176 days; Days to treatment end: 197 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 42 days; Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Other.
- Follow-up contact recording only the day: day 758.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking quit year: 2009.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-90-6837-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.3. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide TCGA-90-6837-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 5.
  Slide TCGA-90-6837-01A-01-BS1: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-90-6837-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-90-6837-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.4; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; Pulmonary function test indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

GDC annotations on this case (curator notes; quoted as recorded):
- BCR Notification (a sample-identity caveat): Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on sample TCGA-90-6837-01A: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-90-6837-01A-11D: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-90-6837-01A-11D-1941-02: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-90-6837-01A-11D-1943-01: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-90-6837-01A-11D-1945-08: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-90-6837-01A-11D-1947-05: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-90-6837-01A-11H: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-90-6837-01A-11H-1948-13: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-90-6837-01A-11R: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-90-6837-01A-11R-1949-07: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-90-6837-01A-11W: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signatures from the DNA and RNA from the tumor and normal tissue, as well as DNA from the blood derived normal, do not cluster with the expected sample types. This suggests the tumor and normal samples may not be labeled correctly; all genotyping results confirm that all samples are from the same patient. Data from this patient should be used with caution.
- (and 21 further annotations of these kinds)

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 758 days; disease-specific survival: no event (censored), 758 days; disease-free interval: no event (censored), 758 days; progression-free interval: no event (censored), 758 days.
